Somatic mutation profile of tumor specimen MMRF_1605_3_BM_CD138pos (aliquot MMRF_1605_3_BM_CD138pos_T1_KHS5U_L08729) from MMRF case MMRF_1605, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.5 years (17,365 days).
Specimen MMRF_1605_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1482755-95c2-4522-9565-9c942fa7fdd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1605_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1605_1_PB_Whole_C2_KBS5U_L04127; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccbd06a9-3cca-423b-8a9c-7412705755bc

The open-access MAF lists 68 somatic variants for this specimen: 21 protein-altering or splice-affecting, 12 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 19, Missense Mutation 18, Silent 12, Intron 6, 5'UTR 4, 3'Flank 4, Nonsense Mutation 2, RNA 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPSF1 | c.2642C>G p.S881C | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs1158604993, COSV58235803; called by muse, mutect2, varscan2
- EPHB4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs142009811; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV100438456; called by muse, mutect2, varscan2
- HLTF | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1234343390; called by muse, mutect2, varscan2
- IGKJ5 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 142/442 reads (32%) | catalogued as rs142632901; called by muse, varscan2
- KRT1 | c.698C>A p.S233* | Nonsense Mutation (SNP) | VAF 70/229 reads (31%) | catalogued as CM060296; called by muse, mutect2, varscan2
- NKD2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs544544673; called by muse, mutect2
- PADI1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs142259163; called by muse, mutect2, varscan2
- TTN | c.13999G>A p.V4667M (on ENST00000591111; = p.V3740M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/225 reads (31%) | PolyPhen possibly damaging (0.743); catalogued as rs903648091; called by muse, mutect2, varscan2
- ZNF131 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 80/940 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373229883; called by muse, mutect2
- ADAMTS2 | c.952A>T p.I318F | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- CDH18 | c.804T>G p.F268L | Missense Mutation (SNP) | VAF 139/268 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- DNAJC5 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 236/779 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- FASTKD3 | c.1454T>G p.L485W | Missense Mutation (SNP) | VAF 50/479 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IQCE | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 80/623 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MIA3 | c.5510C>G p.P1837R | Missense Mutation (SNP) | VAF 166/486 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- NFE2L1 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 131/616 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- RBP3 | c.1683G>A p.W561* | Nonsense Mutation (SNP) | VAF 71/235 reads (30%) | called by muse, mutect2, varscan2
- SETDB2 | c.1753A>T p.I585F | Missense Mutation (SNP) | VAF 150/326 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- TMUB2 | c.403G>C p.E135Q (on ENST00000538716 / NM_001353177.2; = p.E115Q on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/402 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TRAF3 | c.1021del p.R341Gfs*10 | Frame Shift Del (DEL) | VAF 25/213 reads (12%) | called by mutect2, varscan2
- CST2 | c.291C>T p.S97= | Silent (SNP) | VAF 30/470 reads (6%) | called by muse, mutect2
- DSG3 | c.891C>T p.Y297= | Silent (SNP) | VAF 61/178 reads (34%) | called by muse, mutect2, varscan2
- DTHD1 | c.1848C>T p.T616= (on ENST00000456874; = p.T451= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/253 reads (40%) | called by muse, mutect2, varscan2
- HHATL | c.264A>G p.K88= | Silent (SNP) | VAF 129/399 reads (32%) | catalogued as rs913745816; called by muse, mutect2, varscan2
- HLTF | c.786A>T p.P262= | Silent (SNP) | VAF 64/191 reads (34%) | called by muse, mutect2, varscan2
- LINGO2 | c.1521T>C p.R507= | Silent (SNP) | VAF 136/440 reads (31%) | called by muse, mutect2, varscan2
- LRP1B | c.4788C>T p.F1596= | Silent (SNP) | VAF 110/373 reads (29%) | called by muse, mutect2, varscan2
- SLC7A7 | c.441C>T p.L147= | Silent (SNP) | VAF 63/147 reads (43%) | called by muse, mutect2, varscan2
- SPEF2 | c.90T>C p.S30= | Silent (SNP) | VAF 294/558 reads (53%) | called by muse, mutect2, varscan2
- SYNCRIP | c.948T>C p.N316= | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- TBC1D20 | c.1110G>A p.L370= | Silent (SNP) | VAF 36/302 reads (12%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.370C>T p.L124= | Silent (SNP) | VAF 37/397 reads (9%) | called by muse, mutect2
- ADRB1 | c.-209G>A | 5'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- ALPP | c.*1054A>G | 3'UTR (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021570 C>T | 5'Flank (SNP) | VAF 59/182 reads (32%) | catalogued as rs551915100, COSV55848051; called by muse, mutect2, varscan2
- CACNA1E | c.*5964G>A | 3'UTR (SNP) | VAF 56/203 reads (28%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65883743 A>C | 3'Flank (SNP) | VAF 72/181 reads (40%) | called by muse, mutect2, varscan2
- CEP78 | c.*1983G>A | 3'UTR (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- CHRD | c.1933-13C>T | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- CLDN9 | c.*446A>G | 3'UTR (SNP) | VAF 227/703 reads (32%) | catalogued as rs781736331; called by muse, mutect2, varscan2
- CNOT7 | c.*1396G>T | 3'UTR (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
- CNOT7 | c.*1395G>A | 3'UTR (SNP) | VAF 87/214 reads (41%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+562G>A | Intron (SNP) | VAF 54/161 reads (34%) | catalogued as rs1355683074; called by muse, mutect2, varscan2
- DDX25 | c.*2645C>T | 3'UTR (SNP) | VAF 60/570 reads (11%) | catalogued as rs1409161084; called by muse, mutect2
- DENND10 | c.-9del | 5'UTR (DEL) | VAF 10/81 reads (12%) | called by mutect2, pindel, varscan2
- EIF3I | c.-5C>T | 5'UTR (SNP) | VAF 36/746 reads (5%) | catalogued as rs1306094040; called by muse, mutect2
- ESPNP | n.1455G>C | RNA (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- FAF2 | c.*1106G>A | 3'UTR (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- FAF2 | c.*2380del | 3'UTR (DEL) | VAF 88/221 reads (40%) | called by mutect2, pindel, varscan2
- FGL1 | c.-17-124G>A | Intron (SNP) | VAF 38/449 reads (8%) | called by muse, mutect2
- IRAK3 | c.*3588C>T | 3'UTR (SNP) | VAF 58/169 reads (34%) | called by muse, mutect2, varscan2
- KCNE4 | c.*651del | 3'UTR (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- KIF13A | chr6:17759557 C>A | 3'Flank (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- MANEA | c.*348C>T | 3'UTR (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- MINDY2 | c.*1857C>T | 3'UTR (SNP) | VAF 251/804 reads (31%) | called by muse, mutect2, varscan2
- NAP1L3 | c.*390A>G | 3'UTR (SNP) | VAF 59/102 reads (58%) | catalogued as rs886072294; called by muse, mutect2, varscan2
- NOC2L | c.179+10G>A | Intron (SNP) | VAF 41/277 reads (15%) | called by muse, mutect2, varscan2
- OOSP3 | chr11:59898368 C>T | 3'Flank (SNP) | VAF 54/580 reads (9%) | catalogued as rs902722639; called by muse, mutect2, varscan2
- PEG3 | c.*4C>T | 3'UTR (SNP) | VAF 117/322 reads (36%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-1027A>G | Intron (SNP) | VAF 217/697 reads (31%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20318328 C>G | 3'Flank (SNP) | VAF 22/200 reads (11%) | called by muse, mutect2, varscan2
- TCF7L2 | c.*948A>G | 3'UTR (SNP) | VAF 65/211 reads (31%) | catalogued as rs935036732; called by muse, mutect2, varscan2
- TOMM20 | c.*169T>G | 3'UTR (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- TYR | c.-27G>A | 5'UTR (SNP) | VAF 37/107 reads (35%) | catalogued as rs1406673459; called by muse, mutect2, varscan2
- USP42 | c.442+1181G>C | Intron (SNP) | VAF 21/380 reads (6%) | called by muse, mutect2
- XPNPEP3 | c.*5806A>G | 3'UTR (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- ZNF528 | c.*1438G>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
